Gene-level copy-number profile of specimen HCM-CSHL-0664-C18-85M from HCMI case HCM-CSHL-0664-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.4 years (22,442 days).
Specimen HCM-CSHL-0664-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a63d228-49d9-4597-a4f1-3aa052270049.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0664-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/59c6bb98-3a48-4be1-a975-8b91a8ffe1fe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 1; copy number 2: 11,742; copy number 3: 20,467; copy number 4: 17,134; copy number 5: 5,427; copy number 6: 2,176; copy number 7: 961; copy number 8: 482; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,445 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:53,497,341–58,438,364, 62 genes, copy number 7 (broad region; genes not listed).
- chr8:55,102,028–145,066,685, 1,365 genes, copy number 7–8 (broad region; genes not listed).
- chr21:38,733,890–39,183,488, 14 genes, copy number 7: LINC00114, ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1.
- chr21:39,216,624–39,219,805, 2 genes, copy number 7 (within-gene range 5–7): TIMM9P2, BRWD1-IT1.
- chr22:18,178,038–18,345,899, 2 genes, copy number 11: FAM230D, GGTLC5P.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
